Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADJ-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma

Specimen : Liver

Photo :

GROSS:

Specimen:

Liver (16.0 x 9.5 x 2.5 cm, 250 gm, unfixed)

Gallbladder (6.2 cm in length, 3.2 cm in diameter, 0.2 cm in wall thickness, unfixed)

Operation: Partial hepatectomy

Lesion:

- A well-defined mass: 2.5 x 2.5 x 2.0 cm at the segment 4

- Cut surface:

Round to ovoid, pale tan to yellow, and solid mass with hemorrhage and necrosis (30-40 %)

Gross type:

HCC: Expanding nodular

Resection margin:

Not involved grossly (safety margin: 0.3 cm)

Others: Satellite nodule: No

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Gross photo: Present

Blocks

T1-5, round to ovoid and solid mass and surrounding tissue x 5

L, cirrhotic liver x 1

RM, blood vessel x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

Edmondson-Steiner grade

The worst grade III

The major grade II

Histologic type: Trabecular and solid

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

Q4 5/20/14

[page 2 of 2]
Multicentric occurrence: No

NOT reported. Gross:

cervix, smear, inflammation

Cervix, smear, atrophy

Cervix, smear, inflammation, atrophy

Large intestine, cecum, scopic, suggestive of, hyperplastic polyp

Liver, ectomy, hepatocellular carcinoma, cirrhosis

T56000, P10, M81703, M49500

Gallbladder, ectomy, chronic cholecystitis

T57000, P10, M43005

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma

Cirrhosis, micronodular

Gallbladder, cholecystectomy:

Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file ee5aac44-4066-40a1-91b2-2caf782144f4 (TCGA-DD-AADJ.D087E915-C5DB-40B1-9EDA-B10EA2D6754B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).